Somatic mutation profile of tumor specimen C3N-02589-01 (aliquot CPT0162660007) from CPTAC case C3N-02589, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.2 years (26,008 days).
Specimen C3N-02589-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1af145b9-9070-43d6-b389-d21e935140a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02589-31 (Blood Derived Normal), aliquot CPT0162700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3d5417c-1efa-44ab-8c78-f4e214ae5956

The open-access MAF lists 53 somatic variants for this specimen: 29 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 21, RNA 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 28/340 reads (8%) | catalogued as rs780020495, COSV99370649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 30/358 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 27/234 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMPH | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 49/530 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs759265550, COSV100341675, COSV57754878; called by muse, mutect2
- COL4A1 | c.4970C>T p.T1657M | Missense Mutation (SNP) | VAF 42/669 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs779139113, COSV65427289; called by muse, mutect2
- DERPC | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.182); catalogued as rs1378529846; called by muse, mutect2
- DOCK2 | c.5086C>T p.R1696W | Missense Mutation (SNP) | VAF 27/425 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs980056604, COSV56944050; ClinVar: uncertain significance; called by muse, mutect2
- FAM9B | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs201073413; called by muse, mutect2, varscan2
- KCNA5 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 63/590 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767170268, COSV52908801; called by muse, mutect2, varscan2
- MMP25 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs370333247; called by muse, mutect2, varscan2
- OR8H3 | c.454G>C p.G152R | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV57910324; called by muse, mutect2
- PXDNL | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV62478104, COSV62493633; called by muse, mutect2
- SATB2 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 36/549 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1321695489, COSV53481443, COSV53494145; called by muse, mutect2
- SHANK1 | c.6220C>T p.R2074C | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs549670535, COSV53252620, COSV53263287; called by muse, mutect2, varscan2
- SLC17A8 | c.1375C>A p.L459I | Missense Mutation (SNP) | VAF 17/544 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.383); catalogued as COSV60124316; called by muse, mutect2
- TBX5 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs145784562; ClinVar: uncertain significance; called by muse, mutect2
- TCTE1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs750220971, COSV65255298; called by muse, mutect2, varscan2
- TSSK1B | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560296208; called by muse, mutect2
- ZAR1L | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV61525160; called by muse, mutect2, varscan2
- ZNF544 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs756389353; called by muse, mutect2
- ZZEF1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs748685711; called by muse, mutect2
- ANKRD30B | c.1960A>T p.T654S | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.866); called by muse, mutect2
- BARHL2 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 61/693 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- CACNA1H | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.223); called by muse, mutect2
- DAP3 | c.1097T>A p.L366H | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DLG5 | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- KRT6A | c.113T>G p.V38G | Missense Mutation (SNP) | VAF 106/1056 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ZNF627 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- ZNF804B | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- AGPAT1 | c.717G>A p.T239= | Silent (SNP) | VAF 28/304 reads (9%) | catalogued as rs937993066, COSV61247738, COSV61247900; called by muse, mutect2
- AIRE | c.615C>T p.A205= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as rs143784684; called by muse, mutect2
- ARHGAP17 | c.639T>A p.V213= | Silent (SNP) | VAF 25/275 reads (9%) | called by muse, mutect2
- DPY19L2 | c.948T>A p.I316= | Silent (SNP) | VAF 27/219 reads (12%) | called by muse, mutect2, varscan2
- EGLN1 | c.864C>A p.G288= | Silent (SNP) | VAF 102/654 reads (16%) | called by muse, mutect2, varscan2
- FMN1 | c.432C>T p.P144= | Silent (SNP) | VAF 34/345 reads (10%) | catalogued as rs193208337; called by muse, mutect2, varscan2
- GLI2 | c.2940G>A p.P980= (on ENST00000361492 / NM_001374353.1; = p.P997= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/592 reads (8%) | called by muse, mutect2
- HTR3B | c.600G>A p.A200= | Silent (SNP) | VAF 16/266 reads (6%) | catalogued as rs117682771; called by muse, mutect2
- KIF7 | c.1110C>T p.S370= | Silent (SNP) | VAF 25/301 reads (8%) | called by muse, mutect2
- LEF1 | c.579C>T p.I193= | Silent (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- OR2T3 | c.771C>T p.F257= | Silent (SNP) | VAF 24/438 reads (5%) | catalogued as rs1451157176, COSV62081928; called by muse, mutect2
- POM121C | c.672A>G p.T224= | Silent (SNP) | VAF 42/527 reads (8%) | catalogued as rs1554474011; called by muse, mutect2
- PRKD1 | c.2622C>T p.G874= | Silent (SNP) | VAF 62/708 reads (9%) | catalogued as rs767961425; called by muse, mutect2
- RNF31 | c.2907C>T p.C969= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs1566618301; called by muse, mutect2
- SLA | c.30G>A p.A10= (on ENST00000338087 / NM_001045556.3; = p.A50= on NM_006748.4) | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs202000953, COSV99598584; called by muse, varscan2
- SLC2A5 | c.957C>T p.A319= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as rs1227581337, COSV66237760; called by muse, mutect2
- SRCAP | c.4500G>A p.P1500= | Silent (SNP) | VAF 30/293 reads (10%) | catalogued as rs574491718; called by muse, mutect2, varscan2
- SVEP1 | c.5841T>C p.A1947= | Silent (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- TAP2 | c.867G>A p.S289= | Silent (SNP) | VAF 78/890 reads (9%) | catalogued as rs775338272, COSV66499058; ClinVar: likely benign; called by muse, mutect2
- TMEM61 | c.162G>A p.T54= | Silent (SNP) | VAF 30/328 reads (9%) | catalogued as rs922467669, COSV100987742; called by muse, mutect2
- ZFP37 | c.987C>G p.A329= | Silent (SNP) | VAF 20/213 reads (9%) | catalogued as COSV65289086; called by muse, mutect2
- MIR99A | n.57G>A | RNA (SNP) | VAF 6/132 reads (5%) | catalogued as rs913397001; called by muse, mutect2
- OR52A4P | n.796C>T | RNA (SNP) | VAF 8/57 reads (14%) | catalogued as rs753901401; called by muse, mutect2, varscan2
- TNRC18 | chr7:5427976 G>C | 5'Flank (SNP) | VAF 37/412 reads (9%) | called by muse, mutect2
